Somatic mutation profile of tumor specimen C3L-01889-01 (aliquot CPT0092240009) from CPTAC case C3L-01889, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 71.7 years (26,205 days).
Specimen C3L-01889-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bfdeb702-5d3c-4879-b081-9d07ad0b28aa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01889-31 (Blood Derived Normal), aliquot CPT0093760002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/115f0d16-dbfc-4bb0-91a3-7eed35060dd3

The open-access MAF lists 254 somatic variants for this specimen: 165 protein-altering or splice-affecting, 70 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 132, Silent 70, Nonsense Mutation 11, Intron 10, Frame Shift Del 9, Splice Site 8, RNA 5, Splice Region 4, 5'UTR 2, Translation Start Site 1, 3'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1862A>G p.N621S (on ENST00000288602 / NM_001374244.1; = p.N581S on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 89/263 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs121913370, COSV56058108, COSV56106422, COSV56110832; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- STK11 | c.367C>T p.Q123* | Nonsense Mutation (SNP) | VAF 28/122 reads (23%) | catalogued as rs1131690925, CM041078, COSV58822494; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACOXL | c.653A>T p.H218L | Missense Mutation (SNP) | VAF 44/173 reads (25%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs778523879; called by muse, mutect2, varscan2
- ADGRB2 | c.520G>T p.A174S | Missense Mutation (SNP) | VAF 96/344 reads (28%) | SIFT tolerated (0.58); PolyPhen benign (0.021); catalogued as rs200554940, COSV57070503; called by muse, mutect2, varscan2
- AFF2 | c.2130C>A p.F710L | Missense Mutation (SNP) | VAF 85/327 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53988627; called by muse, mutect2, varscan2
- ALDH8A1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 11/47 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.91); catalogued as rs149535629; called by muse, mutect2
- ANKEF1 | c.1510G>T p.D504Y | Missense Mutation (SNP) | VAF 68/280 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65693191; called by muse, mutect2, varscan2
- APBA1 | c.896A>G p.D299G | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs1205355914; called by muse, mutect2
- BEND6 | c.778C>A p.L260I | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1254401751; called by muse, mutect2, varscan2
- BICD2 | c.1886A>G p.N629S | Missense Mutation (SNP) | VAF 41/146 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs768918778; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CELSR1 | c.2135G>T p.R712L | Missense Mutation (SNP) | VAF 44/167 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as COSV53089519; called by muse, mutect2, varscan2
- CHRM2 | c.509C>G p.T170S | Missense Mutation (SNP) | VAF 76/281 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV57775645; called by muse, mutect2, varscan2
- COL26A1 | c.83C>T p.S28L | Missense Mutation (SNP) | VAF 9/198 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs1175653802; called by muse, mutect2
- CTBP1 | c.686A>G p.H229R | Missense Mutation (SNP) | VAF 83/307 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs756451089; called by muse, mutect2, varscan2
- DDO | c.937G>T p.V313L (on ENST00000368924 / NM_001368172.1; = p.V254L on NM_004032.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.021); catalogued as COSV64469689; called by muse, mutect2, varscan2
- DNAH11 | c.9403G>A p.E3135K | Missense Mutation (SNP) | VAF 33/136 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as rs777605062, COSV60972460; called by muse, mutect2, varscan2
- DRD1 | c.54G>T p.R18S | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.001); catalogued as rs758745722; called by muse, mutect2
- GPR135 | c.1385G>C p.R462P | Missense Mutation (SNP) | VAF 35/152 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.32); catalogued as COSV67749555, COSV67749646; called by muse, mutect2, varscan2
- IGDCC3 | c.1883G>T p.R628L | Missense Mutation (SNP) | VAF 61/192 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV60076388; called by muse, mutect2, varscan2
- KEAP1 | c.772G>T p.E258* | Nonsense Mutation (SNP) | VAF 86/220 reads (39%) | catalogued as COSV50284808; called by muse, mutect2, varscan2
- KMT2E | c.2209G>T p.E737* | Nonsense Mutation (SNP) | VAF 26/91 reads (29%) | catalogued as COSV57577627; called by muse, varscan2
- LATS2 | c.119G>T p.G40V | Missense Mutation (SNP) | VAF 80/310 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.044); catalogued as COSV66880040; called by mutect2, varscan2
- LRP1B | c.11916G>T p.R3972S | Missense Mutation (SNP) | VAF 47/173 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.977); catalogued as COSV101261453; called by muse, mutect2, varscan2
- MAD1L1 | c.107C>T p.S36L | Missense Mutation (SNP) | VAF 35/166 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.146); catalogued as rs776910007, COSV54247991; called by muse, mutect2, varscan2
- MAGEC3 | c.994G>T p.E332* | Nonsense Mutation (SNP) | VAF 57/187 reads (30%) | catalogued as COSV53579858, COSV68924101; called by muse, mutect2, varscan2
- MLLT1 | c.193G>T p.V65L | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as rs781772134; called by muse, mutect2, varscan2
- MPEG1 | c.1426G>A p.G476R | Missense Mutation (SNP) | VAF 14/137 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99914867; called by muse, mutect2, varscan2
- MTBP | c.1810A>G p.K604E | Missense Mutation (SNP) | VAF 41/195 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs969385467; called by muse, mutect2, varscan2
- NSD1 | c.3880C>T p.P1294S | Missense Mutation (SNP) | VAF 84/316 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs761564636; called by muse, mutect2, varscan2
- NYAP2 | c.1507C>T p.R503W | Missense Mutation (SNP) | VAF 57/272 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs752903462, COSV56004733; called by muse, mutect2, varscan2
- OLIG3 | c.539C>A p.P180Q | Missense Mutation (SNP) | VAF 46/147 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs549681127; called by muse, mutect2, varscan2
- OR14C36 | c.683G>T p.R228I | Missense Mutation (SNP) | VAF 54/274 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1415558005; called by muse, mutect2, varscan2
- OR1C1 | c.866T>A p.I289N | Missense Mutation (SNP) | VAF 46/215 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761633943; called by muse, mutect2, varscan2
- OR2F2 | c.455G>T p.G152V | Missense Mutation (SNP) | VAF 39/168 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68833217; called by muse, mutect2, varscan2
- OR52N2 | c.176G>A p.R59Q | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.49); PolyPhen benign (0.022); catalogued as rs754168631, COSV57676080; called by muse, mutect2
- OR6V1 | c.842C>A p.P281H | Missense Mutation (SNP) | VAF 51/223 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101389367; called by muse, mutect2, varscan2
- PAXBP1 | c.8G>A p.R3Q | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.054); catalogued as COSV51610626; called by muse, mutect2, varscan2
- PDHA2 | c.385G>A p.V129I | Missense Mutation (SNP) | VAF 46/190 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.065); catalogued as COSV54779912; called by muse, mutect2, varscan2
- PDYN | c.695G>T p.R232L | Missense Mutation (SNP) | VAF 64/183 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774175877, COSV54101517, COSV54102525; called by muse, mutect2, varscan2
- PLEKHG5 | c.3016C>T p.Q1006* (on ENST00000400915 / NM_001042663.3; = p.Q969* on NM_020631.6) | Nonsense Mutation (SNP) | VAF 19/78 reads (24%) | catalogued as rs1422231495; called by muse, mutect2, varscan2
- PLVAP | c.958G>T p.E320* | Nonsense Mutation (SNP) | VAF 37/115 reads (32%) | catalogued as COSV99391684; called by muse, mutect2, varscan2
- PLXNB3 | c.2670-1G>A p.X890_splice | Splice Site (SNP) | VAF 16/68 reads (24%) | catalogued as rs782515710; called by muse, mutect2
- PPARGC1B | c.1585G>T p.D529Y | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as rs749377390; called by muse, mutect2, varscan2
- PRDM9 | c.1762G>T p.G588C | Missense Mutation (SNP) | VAF 53/211 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99690768; called by muse, mutect2, varscan2
- PSIP1 | c.751A>G p.K251E | Missense Mutation (SNP) | VAF 92/353 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as rs1322961362; called by muse, mutect2, varscan2
- RERG | c.566C>T p.A189V | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0.01); catalogued as rs767888721; called by muse, varscan2
- SLC14A2 | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs267605187, COSV99675141; called by muse, mutect2, varscan2
- SLC35B4 | c.811C>T p.L271F | Missense Mutation (SNP) | VAF 54/211 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1233593598; called by muse, mutect2, varscan2
- STX11 | c.629G>A p.R210H | Missense Mutation (SNP) | VAF 22/204 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100845551; called by muse, mutect2, varscan2
- SUSD4 | c.1120G>T p.V374F | Missense Mutation (SNP) | VAF 44/109 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs778519980; called by muse, mutect2, varscan2
- SYNPR | c.11T>A p.V4E | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV71555532; called by muse, mutect2, varscan2
- TCERG1L | c.563A>G p.H188R | Missense Mutation (SNP) | VAF 60/235 reads (26%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs1028352081; called by muse, mutect2, varscan2
- THBS2 | c.707C>A p.A236D | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.209); catalogued as rs368747793; called by muse, mutect2, varscan2
- VEGFC | c.995G>T p.R332L | Missense Mutation (SNP) | VAF 69/268 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.488); catalogued as rs755693482, COSV54606405; called by muse, mutect2, varscan2
- ZNF23 | c.1735C>G p.Q579E | Missense Mutation (SNP) | VAF 45/160 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.723); catalogued as rs758073385; called by muse, mutect2, varscan2
- ZNF630 | c.491G>T p.R164L | Missense Mutation (SNP) | VAF 78/273 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV99332436; called by muse, mutect2, varscan2
- ZSCAN21 | c.373C>T p.R125W | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as rs373816425, COSV52851028; called by muse, mutect2, varscan2
- ADAMTS10 | c.2083T>C p.C695R | Missense Mutation (SNP) | VAF 12/266 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ADAMTSL1 | c.801G>A p.M267I | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ADGB | c.4416del p.W1472* | Frame Shift Del (DEL) | VAF 85/369 reads (23%) | called by mutect2, pindel, varscan2
- ADGRB3 | c.2794C>G p.Q932E | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- AKT3 | c.159C>G p.N53K | Missense Mutation (SNP) | VAF 95/199 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.363); called by muse, mutect2, varscan2
- AMBP | c.899T>C p.I300T | Missense Mutation (SNP) | VAF 45/196 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ANKRD30B | c.2677del p.A893Lfs*7 | Frame Shift Del (DEL) | VAF 34/157 reads (22%) | called by mutect2, pindel, varscan2
- ARHGAP4 | c.2156+8C>A | Splice Region (SNP) | VAF 80/273 reads (29%) | called by muse, mutect2, varscan2
- ATP12A | c.601G>A p.V201M | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- ATP5F1D | c.172G>C p.V58L | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- BAZ2B | c.322G>T p.A108S | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.025); called by muse, mutect2
- BBOX1 | c.956A>G p.D319G | Missense Mutation (SNP) | VAF 38/166 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- BCORL1 | c.3167G>C p.G1056A | Missense Mutation (SNP) | VAF 70/275 reads (25%) | SIFT tolerated (0.66); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- BOD1L2 | c.71G>T p.G24V | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.394); called by muse, mutect2, varscan2
- CAGE1 | c.2110T>C p.L704= (on ENST00000512086; = p.L568= on NM_205864.3) | Splice Region (SNP) | VAF 42/162 reads (26%) | called by muse, mutect2, varscan2
- CCDC117 | c.239_239+5del p.X80_splice | Splice Site (DEL) | VAF 24/135 reads (18%) | called by mutect2, pindel, varscan2
- CCDC169 | c.628C>T p.P210S | Missense Mutation (SNP) | VAF 46/171 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.457); called by muse, mutect2, varscan2
- CCDC74B | c.796C>A p.L266M | Missense Mutation (SNP) | VAF 35/150 reads (23%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CCR1 | c.802del p.L268Cfs*18 | Frame Shift Del (DEL) | VAF 35/156 reads (22%) | called by mutect2, pindel, varscan2
- CEP57 | c.622-2A>G p.X208_splice | Splice Site (SNP) | VAF 74/265 reads (28%) | called by muse, mutect2, varscan2
- CNGA3 | c.747C>A p.F249L | Missense Mutation (SNP) | VAF 54/183 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- CNTNAP2 | c.2229T>A p.C743* | Nonsense Mutation (SNP) | VAF 109/376 reads (29%) | called by muse, mutect2, varscan2
- CNTNAP4 | c.3470C>A p.A1157E | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.015); called by muse, mutect2
- CNTNAP4 | c.3472C>A p.L1158M | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.839); called by muse, mutect2
- COG7 | c.1082A>G p.K361R | Missense Mutation (SNP) | VAF 102/385 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- COL11A1 | c.2935G>T p.G979C | Missense Mutation (SNP) | VAF 67/247 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CPNE5 | c.1096G>T p.V366F | Missense Mutation (SNP) | VAF 56/197 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CSMD2 | c.9971A>T p.Y3324F | Missense Mutation (SNP) | VAF 35/126 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- CTSS | c.611_627+21del p.X204_splice | Splice Site (DEL) | VAF 16/151 reads (11%) | called by mutect2, pindel
- CWC25 | c.84G>T p.Q28H | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DEAF1 | c.457A>T p.T153S | Missense Mutation (SNP) | VAF 64/237 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- DIP2A | c.3427C>A p.P1143T | Missense Mutation (SNP) | VAF 137/337 reads (41%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- DMD | c.1179G>T p.Q393H | Missense Mutation (SNP) | VAF 65/289 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DMRTA2 | c.1534C>A p.R512S | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- DOCK2 | c.2643G>C p.E881D | Missense Mutation (SNP) | VAF 44/148 reads (30%) | SIFT tolerated (0.51); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EPHA6 | c.397G>C p.D133H | Missense Mutation (SNP) | VAF 35/173 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAM43A | c.449C>T p.P150L | Missense Mutation (SNP) | VAF 32/153 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FCGRT | c.550C>T p.H184Y | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- FOXD4L6 | c.1196C>A p.A399E | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.51); called by mutect2, varscan2
- FUT8 | c.1357G>T p.D453Y (on ENST00000360689 / NM_001371534.1; = p.D290Y on NM_004480.4) | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GARNL3 | c.1805G>T p.R602M | Missense Mutation (SNP) | VAF 38/164 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- GPCPD1 | c.1481C>T p.S494F | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.378); called by muse, mutect2, varscan2
- GRIK2 | c.2033C>A p.T678N | Missense Mutation (SNP) | VAF 51/232 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GRIK3 | c.51del p.L19Sfs*35 | Frame Shift Del (DEL) | VAF 27/154 reads (18%) | called by mutect2, pindel, varscan2
- GRIN2B | c.3722G>T p.R1241L | Missense Mutation (SNP) | VAF 53/239 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- GRM8 | c.2252G>T p.C751F | Missense Mutation (SNP) | VAF 36/125 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- HELZ | c.520G>A p.G174R | Missense Mutation (SNP) | VAF 219/369 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- HS6ST3 | c.563G>T p.R188L | Missense Mutation (SNP) | VAF 60/187 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HSD11B1 | c.194C>A p.A65E | Missense Mutation (SNP) | VAF 57/309 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- HSD17B12 | c.456+2dup p.X152_splice | Splice Site (INS) | VAF 13/57 reads (23%) | called by mutect2, pindel, varscan2
- IGHV1OR21-1 | c.17G>C p.R6T | Missense Mutation (SNP) | VAF 24/294 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.085); called by muse, mutect2
- IGLV2-18 | c.50C>A p.S17Y | Missense Mutation (SNP) | VAF 85/329 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- IL15 | c.93_102del p.H32Ffs*17 | Frame Shift Del (DEL) | VAF 77/351 reads (22%) | called by mutect2, pindel, varscan2
- JADE1 | c.1132C>G p.L378V | Missense Mutation (SNP) | VAF 69/278 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIR2DL1 | c.664+1G>T p.X222_splice | Splice Site (SNP) | VAF 41/103 reads (40%) | called by muse, mutect2, varscan2
- LAMA2 | c.6020C>A p.A2007D | Missense Mutation (SNP) | VAF 61/261 reads (23%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- LPCAT1 | c.328G>T p.G110C | Missense Mutation (SNP) | VAF 47/206 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- LRGUK | c.2160C>A p.D720E | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LRP2 | c.6622G>C p.D2208H | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRRTM3 | c.1069A>T p.N357Y | Missense Mutation (SNP) | VAF 68/268 reads (25%) | SIFT tolerated (0.76); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- LRTOMT | c.518A>C p.E173A | Missense Mutation (SNP) | VAF 65/275 reads (24%) | SIFT tolerated (0.68); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- MAOB | c.635G>T p.G212V | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAP1B | c.67T>G p.S23A | Missense Mutation (SNP) | VAF 42/210 reads (20%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAPK14 | c.610G>T p.V204F | Missense Mutation (SNP) | VAF 67/213 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MUC17 | c.5789G>T p.S1930I | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- MUC5B | c.16968C>T p.D5656= | Splice Region (SNP) | VAF 38/139 reads (27%) | called by muse, mutect2, varscan2
- MYT1L | c.3447C>A p.Y1149* | Nonsense Mutation (SNP) | VAF 26/88 reads (30%) | called by muse, mutect2, varscan2
- NBAS | c.139G>C p.G47R | Missense Mutation (SNP) | VAF 55/258 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- NEURL1B | c.1090G>T p.D364Y | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- NFASC | c.133A>T p.K45* (on ENST00000339876 / NM_001378329.1; = p.K39* on NM_015090.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 91/219 reads (42%) | called by muse, mutect2, varscan2
- NPC1L1 | c.21G>T p.R7S | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- NRXN1 | c.418G>T p.V140F | Missense Mutation (SNP) | VAF 102/382 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NT5C1B | c.167T>A p.F56Y | Missense Mutation (SNP) | VAF 22/162 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- NXPE1 | c.731G>T p.C244F (on ENST00000424269; = p.C102F on NM_152315.5) | Missense Mutation (SNP) | VAF 43/187 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR13C3 | c.37G>T p.A13S | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); called by muse, varscan2
- OR4K5 | c.422G>T p.C141F | Missense Mutation (SNP) | VAF 15/278 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); called by muse, mutect2
- OR5T3 | c.323G>C p.G108A | Missense Mutation (SNP) | VAF 76/265 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- ORAI1 | c.544A>T p.I182F | Missense Mutation (SNP) | VAF 110/308 reads (36%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- OTOG | c.2894G>T p.C965F | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- PAK3 | c.1427C>A p.P476H (on ENST00000262836 / NM_001324328.2; = p.P461H on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 75/304 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PARS2 | c.56G>T p.R19L | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- PIWIL1 | c.653+2T>A p.X218_splice | Splice Site (SNP) | VAF 33/192 reads (17%) | called by muse, varscan2
- PUF60 | c.630G>T p.Q210H (on ENST00000526683 / NM_001362896.2; = p.Q193H on NM_014281.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 85/313 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- PXDNL | c.2437G>T p.D813Y | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RNF43 | c.383T>A p.M128K | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- ROBO3 | c.4061G>T p.S1354I | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- RUNX2 | c.922A>T p.S308C | Missense Mutation (SNP) | VAF 75/293 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- SEMA4A | c.629G>A p.R210H | Missense Mutation (SNP) | VAF 18/612 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SLC16A14 | c.185T>A p.L62Q | Missense Mutation (SNP) | VAF 31/139 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC4A1 | c.1087+1G>A p.X363_splice | Splice Site (SNP) | VAF 44/117 reads (38%) | called by muse, mutect2, varscan2
- SMC1A | c.2294T>A p.L765* | Nonsense Mutation (SNP) | VAF 124/456 reads (27%) | called by muse, mutect2, varscan2
- SP140 | c.2004C>G p.Y668* | Nonsense Mutation (SNP) | VAF 22/104 reads (21%) | called by muse, varscan2
- SSC4D | c.945C>G p.S315= | Splice Region (SNP) | VAF 42/137 reads (31%) | called by muse, mutect2, varscan2
- ST6GALNAC5 | c.551A>T p.Q184L | Missense Mutation (SNP) | VAF 20/85 reads (24%) | PolyPhen benign (0.003); called by muse, mutect2, varscan2
- STRA6 | c.1645C>A p.L549I | Missense Mutation (SNP) | VAF 37/178 reads (21%) | SIFT tolerated (0.94); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- TAP2 | c.897C>G p.H299Q | Missense Mutation (SNP) | VAF 68/260 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- TCHH | c.601_602delinsT p.T201Lfs*18 | Frame Shift Del (DEL) | VAF 55/314 reads (18%) | called by pindel, varscan2*
- TEX13A | c.778T>G p.W260G | Missense Mutation (SNP) | VAF 78/337 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMEM94 | c.3883G>A p.D1295N | Missense Mutation (SNP) | VAF 40/77 reads (52%) | SIFT tolerated (0.42); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- TNFAIP2 | c.1147_1148delinsT p.G383Sfs*4 | Frame Shift Del (DEL) | VAF 24/164 reads (15%) | called by pindel, varscan2*
- TPTE | c.234C>A p.D78E (on ENST00000618007 / NM_199261.4; = p.D60E on NM_199259.4) | Missense Mutation (SNP) | VAF 40/281 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- TRIM47 | c.920A>T p.Q307L | Missense Mutation (SNP) | VAF 139/238 reads (58%) | SIFT tolerated (0.31); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TRIP4 | c.14G>C p.G5A | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TRPV1 | c.1845_1873del p.W616* | Frame Shift Del (DEL) | VAF 73/271 reads (27%) | called by mutect2, pindel
- UGGT2 | c.4133G>T p.W1378L | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WFIKKN2 | c.877G>T p.A293S | Missense Mutation (SNP) | VAF 27/411 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.097); called by muse, mutect2
- ZFHX4 | c.1049C>T p.T350I | Missense Mutation (SNP) | VAF 42/153 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- ZNF679 | c.653del p.G218Afs*127 | Frame Shift Del (DEL) | VAF 38/147 reads (26%) | called by mutect2, pindel, varscan2
- ACOT7 | c.885C>T p.R295= (on ENST00000377855 / NM_181864.3; = p.R285= on NM_007274.4) | Silent (SNP) | VAF 48/188 reads (26%) | catalogued as rs749424998; called by muse, mutect2, varscan2
- ADGRL3 | c.1980C>T p.V660= (on ENST00000506720 / NM_001322402.2; = p.V592= on NM_015236.6) | Silent (SNP) | VAF 49/242 reads (20%) | catalogued as rs975017579, COSV63368255; called by muse, mutect2, varscan2
- AKAP11 | c.2532A>T p.P844= | Silent (SNP) | VAF 50/138 reads (36%) | called by muse, mutect2, varscan2
- ALDH3B2 | c.132G>T p.L44= | Silent (SNP) | VAF 52/171 reads (30%) | called by muse, mutect2, varscan2
- ALG13 | c.429T>A p.P143= | Silent (SNP) | VAF 28/104 reads (27%) | called by muse, mutect2, varscan2
- ARHGAP40 | c.1128C>T p.P376= | Silent (SNP) | VAF 57/196 reads (29%) | called by muse, mutect2, varscan2
- ARHGAP42 | c.1680G>T p.V560= | Silent (SNP) | VAF 61/189 reads (32%) | catalogued as COSV53975181; called by muse, mutect2, varscan2
- ASB2 | c.1158C>T p.G386= | Silent (SNP) | VAF 13/212 reads (6%) | catalogued as rs1185256349, COSV60111435, COSV60112408; called by muse, mutect2
- ATP2B2 | c.1395G>A p.K465= (on ENST00000352432; = p.K431= on NM_001683.5) | Silent (SNP) | VAF 52/203 reads (26%) | catalogued as rs771774308; called by muse, mutect2, varscan2
- BRWD1 | c.3924C>T p.I1308= | Silent (SNP) | VAF 91/231 reads (39%) | called by muse, mutect2, varscan2
- CABIN1 | c.4818C>T p.I1606= | Silent (SNP) | VAF 27/382 reads (7%) | catalogued as rs147606580; called by muse, mutect2
- CD226 | c.771A>T p.T257= | Silent (SNP) | VAF 65/260 reads (25%) | called by muse, mutect2, varscan2
- CDX4 | c.582C>T p.C194= | Silent (SNP) | VAF 76/276 reads (28%) | called by muse, mutect2, varscan2
- CIC | c.2922C>T p.P974= | Silent (SNP) | VAF 123/314 reads (39%) | catalogued as rs1476730356; called by muse, mutect2, varscan2
- CNTN2 | c.2619C>T p.A873= | Silent (SNP) | VAF 40/197 reads (20%) | catalogued as COSV100084894; called by muse, mutect2, varscan2
- CPN2 | c.1359C>A p.G453= | Silent (SNP) | VAF 56/186 reads (30%) | called by muse, mutect2, varscan2
- CWC27 | c.1122G>A p.Q374= | Silent (SNP) | VAF 27/135 reads (20%) | called by muse, mutect2
- DNHD1 | c.474C>T p.H158= | Silent (SNP) | VAF 37/158 reads (23%) | called by muse, mutect2, varscan2
- FAT4 | c.13422C>T p.L4474= | Silent (SNP) | VAF 49/211 reads (23%) | catalogued as rs753117068; called by muse, mutect2, varscan2
- FCGRT | c.549G>A p.P183= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as rs1036479769; called by muse, mutect2, varscan2
- FZD1 | c.804G>A p.A268= | Silent (SNP) | VAF 16/61 reads (26%) | called by muse, mutect2, varscan2
- GFRA1 | c.519G>C p.A173= | Silent (SNP) | VAF 45/164 reads (27%) | called by muse, mutect2, varscan2
- HAPLN1 | c.708G>A p.R236= | Silent (SNP) | VAF 27/89 reads (30%) | catalogued as rs1325070295, COSV99165053; called by muse, mutect2, varscan2
- HNRNPA0 | c.330T>A p.A110= | Silent (SNP) | VAF 58/221 reads (26%) | called by muse, mutect2, varscan2
- ITGA8 | c.507C>A p.G169= | Silent (SNP) | VAF 47/221 reads (21%) | called by muse, mutect2, varscan2
- KDM5A | c.5010A>C p.A1670= | Silent (SNP) | VAF 76/265 reads (29%) | called by muse, mutect2, varscan2
- KEL | c.1983C>A p.V661= | Silent (SNP) | VAF 73/291 reads (25%) | called by muse, mutect2, varscan2
- KIF26A | c.1668C>A p.P556= | Silent (SNP) | VAF 21/78 reads (27%) | called by muse, mutect2, varscan2
- KLHL1 | c.1287G>T p.L429= | Silent (SNP) | VAF 26/107 reads (24%) | called by muse, mutect2, varscan2
- KRT77 | c.657C>T p.I219= | Silent (SNP) | VAF 80/344 reads (23%) | catalogued as rs760106782, COSV59239502; called by muse, mutect2, varscan2
- KTI12 | c.795C>T p.L265= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as rs1490469633; called by muse, mutect2, varscan2
- MICAL3 | c.630T>C p.P210= | Silent (SNP) | VAF 28/118 reads (24%) | catalogued as COSV99262414; called by muse, mutect2, varscan2
- MRPL27 | c.36A>T p.T12= | Silent (SNP) | VAF 60/499 reads (12%) | called by muse, mutect2, varscan2
- NETO1 | c.561A>G p.Q187= | Silent (SNP) | VAF 74/287 reads (26%) | called by muse, mutect2, varscan2
- NIP7 | c.300G>A p.K100= | Silent (SNP) | VAF 40/128 reads (31%) | called by muse, mutect2, varscan2
- NPC1L1 | c.1197G>A p.Q399= | Silent (SNP) | VAF 34/442 reads (8%) | called by muse, mutect2
- NUDT10 | c.138C>A p.I46= | Silent (SNP) | VAF 33/138 reads (24%) | called by muse, mutect2, varscan2
- OCSTAMP | c.1407C>G p.V469= | Silent (SNP) | VAF 78/281 reads (28%) | catalogued as COSV99645444; called by muse, mutect2, varscan2
- OR4D5 | c.810C>T p.A270= | Silent (SNP) | VAF 45/187 reads (24%) | catalogued as rs1244893409, COSV100189713, COSV58306193; called by muse, mutect2, varscan2
- OR52N2 | c.177G>T p.R59= | Silent (SNP) | VAF 22/82 reads (27%) | called by muse, mutect2
- OR5H15 | c.78C>A p.P26= | Silent (SNP) | VAF 67/270 reads (25%) | catalogued as COSV100736665; called by muse, mutect2, varscan2
- ORC2 | c.597A>G p.E199= | Silent (SNP) | VAF 59/226 reads (26%) | called by muse, mutect2, varscan2
- PCDHA1 | c.1452G>A p.A484= | Silent (SNP) | VAF 19/584 reads (3%) | catalogued as rs782500968, COSV65375169; called by muse, mutect2
- PCDHB9 | c.1479C>A p.P493= | Silent (SNP) | VAF 152/510 reads (30%) | catalogued as COSV53382587; called by muse, mutect2, varscan2
- PDK3 | c.1128A>T p.A376= | Silent (SNP) | VAF 32/123 reads (26%) | called by muse, mutect2, varscan2
- PNLIPRP1 | c.411C>A p.A137= | Silent (SNP) | VAF 62/259 reads (24%) | catalogued as COSV62610878; called by muse, mutect2, varscan2
- PPP1CC | c.156A>T p.L52= | Silent (SNP) | VAF 32/83 reads (39%) | called by muse, varscan2
- PPP2R3C | c.165C>T p.T55= | Silent (SNP) | VAF 25/114 reads (22%) | called by muse, mutect2, varscan2
- ROBO3 | c.4062C>T p.S1354= | Silent (SNP) | VAF 28/121 reads (23%) | called by muse, mutect2, varscan2
- RYR1 | c.12450G>A p.S4150= | Silent (SNP) | VAF 8/204 reads (4%) | called by muse, mutect2
- RYR2 | c.9426C>T p.T3142= | Silent (SNP) | VAF 39/266 reads (15%) | catalogued as COSV100772422; called by muse, mutect2, varscan2
- SCN11A | c.942C>A p.G314= | Silent (SNP) | VAF 51/215 reads (24%) | called by muse, mutect2, varscan2
- SH2B1 | c.1305G>A p.S435= | Silent (SNP) | VAF 20/70 reads (29%) | catalogued as rs765163246; called by muse, mutect2, varscan2
- SHC3 | c.1602G>T p.T534= | Silent (SNP) | VAF 51/158 reads (32%) | catalogued as COSV65436677; called by muse, mutect2, varscan2
- SHQ1 | c.1152A>G p.S384= | Silent (SNP) | VAF 61/239 reads (26%) | called by muse, mutect2, varscan2
- SLC38A5 | c.1002C>T p.L334= | Silent (SNP) | VAF 12/188 reads (6%) | catalogued as rs143580047; called by muse, mutect2
- SLITRK4 | c.1815T>C p.G605= | Silent (SNP) | VAF 52/201 reads (26%) | called by muse, mutect2, varscan2
- SPAAR | c.66C>A p.V22= | Silent (SNP) | VAF 76/306 reads (25%) | called by muse, mutect2, varscan2
- STK11 | c.366G>A p.K122= | Silent (SNP) | VAF 28/122 reads (23%) | catalogued as rs376969448; ClinVar: likely benign; called by muse, mutect2, varscan2
- TAF1C | c.1680C>T p.R560= | Silent (SNP) | VAF 8/186 reads (4%) | catalogued as rs1468503089; called by muse, mutect2
- TAOK1 | c.2208G>A p.Q736= | Silent (SNP) | VAF 234/457 reads (51%) | catalogued as rs749417990, COSV55597643; called by muse, mutect2, varscan2
- TEX45 | c.1194G>A p.P398= | Silent (SNP) | VAF 22/60 reads (37%) | catalogued as rs776584000, COSV64463792, COSV64464433; called by muse, mutect2
- TRBV27 | c.156C>A p.S52= | Silent (SNP) | VAF 6/46 reads (13%) | called by muse, mutect2, varscan2
- UNC5A | c.948G>T p.L316= | Silent (SNP) | VAF 35/136 reads (26%) | called by muse, mutect2, varscan2
- VCAN | c.8019G>T p.G2673= | Silent (SNP) | VAF 79/248 reads (32%) | called by muse, mutect2, varscan2
- WDR45B | c.279T>G p.V93= | Silent (SNP) | VAF 100/294 reads (34%) | called by muse, mutect2, varscan2
- ZFHX4 | c.4989C>G p.T1663= | Silent (SNP) | VAF 41/185 reads (22%) | called by muse, mutect2, varscan2
- ZNF133 | c.30C>T p.F10= | Silent (SNP) | VAF 19/173 reads (11%) | called by muse, mutect2, varscan2
- ZNF518A | c.2064G>A p.Q688= | Silent (SNP) | VAF 49/200 reads (25%) | called by muse, mutect2, varscan2
- ZNF615 | c.1101T>A p.T367= | Silent (SNP) | VAF 34/116 reads (29%) | called by muse, mutect2, varscan2
- BNC2 | c.2639+479G>T | Intron (SNP) | VAF 47/219 reads (21%) | called by muse, mutect2, varscan2
- C1orf229 | n.676C>T | RNA (SNP) | VAF 3/30 reads (10%) | catalogued as rs1345632445; called by muse, mutect2
- CDK15 | c.1059-3466C>A | Intron (SNP) | VAF 49/197 reads (25%) | called by muse, mutect2, varscan2
- COILP1 | n.200C>A | RNA (SNP) | VAF 39/126 reads (31%) | called by muse, mutect2, varscan2
- EGFLAM | c.98-32078G>T | Intron (SNP) | VAF 29/140 reads (21%) | called by muse, mutect2
- HOXA7 | chr7:27152936 A>G | 3'Flank (SNP) | VAF 66/202 reads (33%) | called by muse, mutect2, varscan2
- INTS3 | c.2822-59A>G | Intron (SNP) | VAF 57/309 reads (18%) | called by muse, mutect2, varscan2
- KCNIP2 | c.349-26C>T | Intron (SNP) | VAF 65/266 reads (24%) | catalogued as rs751312754, COSV53308472; called by muse, mutect2, varscan2
- KIR3DX1 | n.1253G>T | RNA (SNP) | VAF 43/121 reads (36%) | called by muse, mutect2, varscan2
- MAGEA5 | n.206C>G | RNA (SNP) | VAF 52/164 reads (32%) | called by muse, mutect2, varscan2
- MYZAP | c.-57C>G | 5'UTR (SNP) | VAF 12/47 reads (26%) | called by muse, mutect2, varscan2
- NDUFS7 | c.122+23G>T | Intron (SNP) | VAF 25/65 reads (38%) | called by muse, mutect2, varscan2
- OR2L1P | n.473C>A | RNA (SNP) | VAF 161/433 reads (37%) | called by muse, mutect2, varscan2
- PXDNL | c.*21G>T | 3'UTR (SNP) | VAF 11/42 reads (26%) | catalogued as COSV62501895; called by muse, mutect2, varscan2
- SLC16A7 | c.218-3014T>A | Intron (SNP) | VAF 31/191 reads (16%) | called by muse, mutect2, varscan2
- TRIM11 | c.859+219G>C | Intron (SNP) | VAF 38/172 reads (22%) | catalogued as rs370717256; called by muse, mutect2, varscan2
- UTRN | c.7480-18181A>G | Intron (SNP) | VAF 33/183 reads (18%) | catalogued as rs1562722600; called by muse, mutect2, varscan2
- WNT9B | c.-38C>A | 5'UTR (SNP) | VAF 12/27 reads (44%) | called by muse, mutect2, varscan2
- ZNF521 | c.41-27del | Intron (DEL) | VAF 51/261 reads (20%) | catalogued as rs1273693746; called by mutect2, pindel, varscan2
